Somatic mutation profile of tumor specimen TARGET-10-PANTYP-09A (aliquot TARGET-10-PANTYP-09A-01D) from TARGET case TARGET-10-PANTYP, project TARGET-ALL-P2 (Acute Lymphoblastic Leukemia - Phase II). Sex at birth: female; Vital status: Alive; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 3.1 years (1,138 days).
Specimen TARGET-10-PANTYP-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 46066b1a-9cec-4ea9-88db-2633ead89621.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-10-PANTYP-14A (Bone Marrow Normal), aliquot TARGET-10-PANTYP-14A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/d6317581-fa9d-4815-a68d-18285c17af34

The open-access MAF lists 11 somatic variants for this specimen: 8 protein-altering or splice-affecting, 2 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 7, Silent 2, Frame Shift Ins 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CREBBP | c.4337G>A p.R1446H | Missense Mutation (SNP) | VAF 6/64 reads (9%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1057519884, COSV52112787, COSV52125401, COSV52132241; ClinVar: likely pathogenic; called by muse, mutect2
- CREBBP | c.4336C>T p.R1446C | Missense Mutation (SNP) | VAF 7/62 reads (11%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs398124146, COSV52113365, COSV52115600, COSV52116725; ClinVar: uncertain significance / likely pathogenic; called by muse, mutect2, varscan2
- KATNAL1 | c.1333C>T p.R445C | Missense Mutation (SNP) | VAF 16/119 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); catalogued as rs747851515, COSV66065213; called by muse, mutect2, varscan2
- PLA2G4E | c.397G>A p.V133M | Missense Mutation (SNP) | VAF 5/35 reads (14%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.916); catalogued as rs759986725, COSV68150401; called by muse, mutect2, varscan2
- COL26A1 | c.301C>T p.P101S (on ENST00000313669 / NM_001278563.3; = p.P99S on NM_133457.4) | Missense Mutation (SNP) | VAF 6/42 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.299); called by muse, mutect2, varscan2
- GABRG1 | c.958G>T p.A320S | Missense Mutation (SNP) | VAF 4/29 reads (14%) | SIFT tolerated (0.4); PolyPhen benign (0.173); called by muse, mutect2
- IGKV3-20 | c.347_348insCACCCTT p.*117Tfs*? | Frame Shift Ins (INS) | VAF 5/14 reads (36%) | called by mutect2, pindel*
- PJA1 | c.543G>C p.K181N | Missense Mutation (SNP) | VAF 11/78 reads (14%) | SIFT tolerated (0.07); PolyPhen benign (0.052); called by muse, mutect2, varscan2
- NPAS4 | c.2127C>T p.P709= | Silent (SNP) | VAF 10/82 reads (12%) | catalogued as rs775151559, COSV60649142, COSV60650215; called by muse, mutect2, varscan2
- PLXNA3 | c.1656G>A p.T552= | Silent (SNP) | VAF 16/49 reads (33%) | catalogued as rs149300616, COSV63754158; called by muse, mutect2, varscan2
- DCHS2 | n.176G>A | RNA (SNP) | VAF 7/107 reads (7%) | called by muse, mutect2
